Surgical pathology report (de-identified scan), TCGA case TCGA-56-A5DS, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-A5DS-01A (Primary Tumor).

[page 1 of 3]
Description: /ear old female

Department: [REDACTED]

Encounter Report Inpatient/Outpatient Encounter Report

Transcription Result Type Surgical Pathology ID [REDACTED] Dictation Date/Time [REDACTED] Author [REDACTED]

Authenticated by [REDACTED]

Document Text

SURGERY CASE #: [REDACTED] FINAL

DATE OF SURGERY: [REDACTED]

SURGEON: [REDACTED]

SPECIMEN:

- A. Wedge, right lower lobe lung.
- B. Lung, right lower lobe.
- C. Lung node R10
- D. Lung node R10 - B
- E. Lung node R10 - C

FROZEN SECTION DIAGNOSIS:

- A. Carcinoma. [REDACTED]
- B. Bronchial surgical margin free of tumor.

OPERATIVE PROCEDURE:

Right video-assisted thoracoscopy with lobectomy.

biopsy, right lower lung

PREOPERATIVE DIAGNOSIS:

Right lung mass.

POSTOPERATIVE DIAGNOSIS:

None given.

*****DIAGNOSIS*****

A-E.

1. Type of specimen:
Right lower lobe lobectomy with lymph node biopsies.
2. Tumor type:
Squamous cell carcinoma.
3. Histologic grade:
Poorly differentiated.
4. Tumor size:
3.5 cm.
5. Surgical margins:
All surgical margins free of tumor.
6. Direct extension of tumor:
Not identified.
7. Venous (large vessel) invasion:
Absent.
8. Lymphatic (small vessel) invasion:
Absent.
9. Lymph nodes:
Total number of lymph nodes examined: 3.
Number of lymph nodes involved: 0 (0/3).

[REDACTED]

ICD-O-3

Carcinoma, Squamous Cell NOS
8670/3

Site: R Lung, Lower lobe
C34.3

JW, 12/24/12

[page 2 of 3]
10. Additional pathologic findings:
Mild chronic inflammation and bronchiectasis.

11. TNM STAGING:
pT2a, pN0, pMx

88331, 88307, 88342, 88342, 88342, 88342, 88342, 88331, 88309,
88305, 88305, 88305

MICROSCOPIC EXAMINATION:

- A. Sections of the mass grossly described demonstrate an invasive malignant epithelial neoplasm. The tumor is composed of infiltrating nests of somewhat polygonal cells with distinct cell borders with cells containing a small to moderate amount of cytoplasm and enlarged nuclei with nuclear pleomorphism. There are nests with central necrosis. There are also rare neoplastic cells with dense eosinophilic cytoplasm. There is no definite lymphovascular invasion. The tumor is seen closely approaching, but not involving, the pleural surface. Focal vague lumina differentiation is noted. Immunohistochemistry stains are obtained and the neoplastic cells are positive with cytokeratin 5, positive with cytokeratin 7, negative with cytokeratin 20, negative staining with TTF-1, strong nuclear staining with p63, and negative staining of the tumor cells with Napsin-A. The remainder of the lung demonstrates mild interstitial fibrosis with mildly thickened alveolar septae.
- B. Multiple sections are examined and sections of the bronchial surgical margins are free of tumor. The vascular margins are also free of tumor. No peribronchial lymph node is identified. Sections of the lung at the previous wedge resection site demonstrates hemorrhage with no residual tumor. Random sections of the lung demonstrate mild fibrosis and bronchiectasis.
- C. Sections demonstrate fragments of a benign lymph node with mild anthracotic pigment. There is no malignancy.
- D. Sections are of fragments of a benign lymph node with similar findings as described above. There is no malignancy.
- E. Sections are of fragments of a benign lymph node with similar findings as described above. There is no malignancy.

GROSS:

- A. Received fresh labeled with the patient's name, account number, and "lung wedge, right lower lobe" is a wedge biopsy of lung measuring 8 x 4 x 2 cm. The pleural surface is red-brown and contains an area of retraction measuring 2 cm. The pleural surface is inked in black. Sectioning reveals a 3.5 cm in maximum dimensions ill-defined mass with a tan-gray, mottled cut surface. Representative sections of the mass are submitted for frozen section and following permanent sections in Cassette #1, with touch preparations also performed. The remainder of the specimen is sectioned to demonstrate a red-brown, soft and spongy parenchyma with no additional masses identified. A representative section is submitted for Genomics Project. Additional sections are submitted for permanent in blocks #2 through #4: Cassettes #2 and #3 - additional sections of the mass, #4 - grossly uninvolved lung.
- B. Received labeled "lung, right lower lobe" is a 15 x 8 x 5 cm in maximum dimensions lobectomy specimen. There is a 8 cm staple line at the previous wedge resection site. The specimen is serially sectioned and no residual tumor is grossly identified. The bronchial margin is submitted for frozen section and frozen section diagnosis in block #1. Sections are then submitted for permanent as follows: #2 - Vascular margins and probable peribronchial lymph node. #3 and #4 -

[page 3 of 3]
Sections from previous wedge resection site. #5 - Grossly uninvolved lung. [REDACTED]

- C. Received in Formalin labeled with the patient's name, account number, and "node R10" is a single anthracotic lymph node measuring 1.1 x 0.7 x 0.5 cm. The specimen is bisected and totally submitted in one cassette. TS-1 [REDACTED]
- D. Received in Formalin labeled with the patient's name, account number, and "level 10 R node - B" are multiple fragments of anthracotic lymph node measuring 0.7 x 0.5 x 0.2 cm in aggregate. The specimen is totally submitted in a single cassette. TS-1 [REDACTED]
- E. Received in Formalin labeled with the patient's name, account number, and "R10 - C node" is a single anthracotic lymph node measuring 0.3 x 0.3 x 0.2 cm. The specimen is totally submitted in a single cassette. TS-1 [REDACTED]

Electronically Signed by
[REDACTED], MD

Dictated: Job# [REDACTED]
Transcribed: Doc# [REDACTED] on
cc: [REDACTED], MD
[REDACTED], MD

Transcription History

Service
Date/Time
Filed
Date/Time

[REDACTED]	Treatment Team Report All Treatment Team for Encounter
------------	---

Source: NCI Genomic Data Commons file b9c2ed9d-9cd7-44b9-9209-d01184f1baa2 (TCGA-56-A5DS.17B3CEDD-13C1-4E7A-8FE9-6710C61B1EE6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).